Gene-level copy-number profile of tumor specimen TCGA-CR-7370-01A from TCGA case TCGA-CR-7370, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 72.5 years (26,468 days).
Specimen TCGA-CR-7370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.caf170c4-6760-4bbb-84ec-50d4df7ba762.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7370-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c7123aa-33cf-480f-bd7d-9588dba3d82c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 424; copy number 2: 17,019; copy number 3: 12,124; copy number 4: 19,321; copy number 5: 4,737; copy number 6: 4,726; copy number 7: 400; copy number 8: 297; copy number 10: 387; copy number 11: 62; copy number 17: 118; copy number 18: 156.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7370-01A-11D-2128-01): tumor purity 0.62, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:95,962,001–96,631,085, 8 genes (within-gene range 0–2): AC104123.1, AC008592.2, FABP5P5, MIR583HG, MIR583, RNU6-524P, AC099509.1, AC099509.2.
- chr10:130,104,569–130,184,521, 4 genes: AL139123.1, CTAGE7P, PPIAP32, GLRX3.
- chr19:94,062–474,983, 24 genes: OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1, THEG, AC010641.2, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 723 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:173,396,284–174,286,644, 1 gene, copy number 18 (within-gene range 4–18): NLGN1.
- chr3:173,910,498–198,222,513, 503 genes, copy number 10–18 (broad region; genes not listed).
- chr6:167,607–1,613,897, 32 genes, copy number 10: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1.
- chr9:32,886,601–34,343,711, 67 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr11:83,789,977–83,815,263, 2 genes, copy number 10: AP002370.1, LDHAL6DP.
- chr21:10,328,411–17,894,485, 118 genes, copy number 17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 424. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
